Gene-level copy-number profile of tumor specimen TCGA-23-1031-01A from TCGA case TCGA-23-1031, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 60.8 years (22,225 days).
Specimen TCGA-23-1031-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9d058d5f-d55f-4286-87cb-5654b838ee4e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1031-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/86e2de68-73e5-426e-bce6-f54c7dcfda37

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 895; copy number 2: 19,846; copy number 3: 19,682; copy number 4: 10,335; copy number 5: 4,290; copy number 6: 3,613; copy number 7: 828; copy number 8: 323; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-23-1031-01): tumor purity 0.52, ploidy 3.3, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,152 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,851,549–181,836,880, 586 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr4:64,275,257–64,611,888, 10 genes, copy number 8 (within-gene range 6–8): TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28.
- chr6:35,443,044–36,844,402, 50 genes, copy number 7: MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690, AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1, BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3.
- chr6:49,358,185–53,418,737, 87 genes, copy number 8 (broad region; genes not listed).
- chr7:150,603,561–159,233,377, 167 genes, copy number 7 (broad region; genes not listed).
- chr8:128,405,269–128,564,679, 1 gene, copy number 10: LINC00824.
- chr9:81,410,279–82,780,194, 25 genes, copy number 7: RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12.
- chr12:66,767–7,240,986, 226 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 295. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
